Somatic mutation profile of tumor specimen 0DQU51 from CCDI case PBCFKA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 8.7 years (3,181 days).
Specimen 0DQU51: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 985f7e7f-56f8-42b3-b88a-7d87f87562b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQU5C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a70380ba-196f-4435-9f15-20df6aca2195

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, 3'UTR 2, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 631/1511 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs730880154, CM1212403, COSV62520732, COSV62522404; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FAP | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 303/768 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs1222599559; called by muse, mutect2, varscan2
- GAL3ST3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 340/768 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1478765069; called by muse, mutect2, varscan2
- LIN28A | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 206/706 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs143830906; called by muse, varscan2
- OR4E2 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 354/901 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV100330169; called by muse, mutect2, varscan2
- UACA | c.3132G>C p.L1044F | Missense Mutation (SNP) | VAF 380/992 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427027182, COSV59854506; called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 21/663 reads (3%) | called by muse, mutect2
- CNGA4 | c.1272C>A p.N424K | Missense Mutation (SNP) | VAF 233/1458 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GIGYF1 | c.663_667dup p.G223Efs*124 | Frame Shift Ins (INS) | VAF 304/1434 reads (21%) | called by mutect2, varscan2
- MYH14 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 231/905 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NXPH1 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 393/886 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SLC38A5 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 549/1357 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- SPPL2C | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 381/805 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FLII | c.2469C>T p.L823= | Silent (SNP) | VAF 527/1241 reads (42%) | called by muse, mutect2, varscan2
- GALK1 | c.1116C>T p.Y372= | Silent (SNP) | VAF 710/1609 reads (44%) | catalogued as rs763195503, COSV99564445; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRPK3 | c.1029C>T p.S343= | Silent (SNP) | VAF 20/656 reads (3%) | catalogued as COSV54209613; called by muse, mutect2
- SRPX | c.939G>A p.T313= | Silent (SNP) | VAF 511/1161 reads (44%) | catalogued as rs769730081, COSV100656013; called by muse, mutect2, varscan2
- ZMYM3 | c.1215C>T p.D405= | Silent (SNP) | VAF 130/959 reads (14%) | catalogued as rs751455760, COSV100078070; called by muse, mutect2, varscan2
- CC2D1A | c.2225+16C>T | Intron (SNP) | VAF 106/510 reads (21%) | called by muse, mutect2, varscan2
- CC2D1A | c.2225+17C>T | Intron (SNP) | VAF 108/510 reads (21%) | called by muse, mutect2, varscan2
- NAA30 | c.*56T>A | 3'UTR (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- SLC43A3 | c.*22G>T | 3'UTR (SNP) | VAF 191/442 reads (43%) | called by muse, mutect2, varscan2
